Somatic mutation profile of tumor specimen TCGA-46-3768-01A (aliquot TCGA-46-3768-01A-01D-0983-08) from TCGA case TCGA-46-3768, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 58.3 years (21,307 days).
Specimen TCGA-46-3768-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 115f951c-2a5b-4828-93db-4e1b2b16328e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-46-3768-10A (Blood Derived Normal), aliquot TCGA-46-3768-10A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ede087d3-1685-4bd1-9ca4-b700bacd820e

The open-access MAF lists 298 somatic variants for this specimen: 222 protein-altering or splice-affecting, 69 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 189, Silent 69, Nonsense Mutation 14, Frame Shift Del 10, RNA 4, Frame Shift Ins 3, Splice Site 2, Splice Region 2, Nonstop Mutation 1, 3'UTR 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 42/48 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>C p.R248P | Missense Mutation (SNP) | VAF 28/38 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.799); catalogued as COSV55944553; called by muse, mutect2
- ABCC12 | c.3737T>C p.L1246S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774136629, COSV60911307; called by muse, mutect2, varscan2
- ADGRL3 | c.1969A>G p.T657A (on ENST00000506720 / NM_001322402.2; = p.T589A on NM_015236.6) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.166); catalogued as COSV63368259; called by muse, mutect2
- ANGPTL7 | c.29C>A p.T10N | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); catalogued as COSV63868105; called by muse, mutect2, varscan2
- ANO1 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60280856; called by muse, mutect2, varscan2
- AP5Z1 | c.70T>A p.F24I | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as COSV62240403; called by muse, mutect2, varscan2
- APOB | c.6994G>A p.E2332K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV51922005, COSV51947791; called by muse, mutect2, varscan2
- ARHGAP44 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as rs767616267, COSV52388695; called by muse, mutect2, varscan2
- ATF7IP | c.3118A>G p.T1040A | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as COSV53765783; called by muse, mutect2, varscan2
- ATP8B4 | c.2300T>C p.L767P | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.833); catalogued as COSV52708489; called by muse, mutect2, varscan2
- B4GALT3 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs373721033; called by muse, mutect2, varscan2
- BSN | c.5830C>T p.P1944S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs747380841, COSV56512561; called by muse, mutect2, varscan2
- BTN3A1 | c.1181G>T p.R394I | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50024422; called by muse, mutect2, varscan2
- C2orf16 | c.1232T>A p.L411Q | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV68645301; called by muse, mutect2, varscan2
- C2orf16 | c.1892G>A p.C631Y | Missense Mutation (SNP) | VAF 59/82 reads (72%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV62673586, COSV62677702; called by muse, mutect2, varscan2
- C9orf72 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT tolerated (0.37); PolyPhen benign (0.303); catalogued as COSV66154538; called by muse, mutect2, varscan2
- CASD1 | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51970550; called by muse, mutect2, varscan2
- CCDC158 | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV66355089; called by muse, mutect2, varscan2
- CCDC158 | c.1150-1G>T p.X384_splice | Splice Site (SNP) | VAF 15/25 reads (60%) | catalogued as COSV66355091; called by muse, mutect2, varscan2
- CD160 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as COSV52522584; called by muse, mutect2, varscan2
- CDH18 | c.1257C>G p.Y419* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV56898839; called by muse, mutect2
- CFAP61 | c.803C>A p.P268Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55618048, COSV55626209; called by muse, mutect2, varscan2
- CFHR4 | c.1087T>A p.C363S (on ENST00000367416 / NM_001201551.2; = p.C117S on NM_006684.5) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52223863; called by muse, mutect2
- CLDN12 | c.434C>G p.T145S | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55305950; called by muse, mutect2, varscan2
- CLEC1B | c.299G>T p.S100I | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs775113342, COSV53724653; called by muse, mutect2, varscan2
- CLEC4E | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV55224793; called by muse, mutect2, varscan2
- CMYA5 | c.7219C>T p.P2407S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs374325994; called by muse, mutect2, varscan2
- CNTN5 | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV54276712, COSV54342359; called by muse, mutect2, varscan2
- COG3 | c.1776A>T p.L592F | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV63071143; called by muse, mutect2, varscan2
- COG7 | c.370T>A p.S124T | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV56148996; called by muse, mutect2
- CPAMD8 | c.1708A>T p.T570S (on ENST00000651564; = p.T523S on NM_015692.5) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.209); catalogued as COSV52230690; called by muse, mutect2, varscan2
- CSMD1 | c.7975C>A p.H2659N (on ENST00000520002; = p.H2658N on NM_033225.6) | Missense Mutation (SNP) | VAF 124/182 reads (68%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.446); catalogued as rs965194578, COSV59278036; called by muse, mutect2, varscan2
- CTHRC1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs1309042247, COSV57714889; called by muse, mutect2, varscan2
- CXorf66 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.154); catalogued as rs186251954, COSV65168884; called by muse, mutect2, varscan2
- DDX60 | c.2083A>G p.I695V | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as COSV67094933; called by muse, mutect2, varscan2
- DENND2A | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755029421, COSV52047141; called by muse, mutect2, varscan2
- DLC1 | c.2321T>A p.M774K (on ENST00000276297 / NM_001348081.2; = p.M337K on NM_006094.5) | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV52288718; called by muse, mutect2, varscan2
- DLG2 | c.1579G>T p.G527W | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54618813; called by muse, mutect2, varscan2
- DMRT1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs573886620, COSV66518772; called by mutect2, varscan2
- DNAH10 | c.4556A>G p.Q1519R (on ENST00000409039; = p.Q1458R on NM_207437.3) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV68987432; called by muse, mutect2, varscan2
- DNAH2 | c.9513G>T p.K3171N | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV66715944; called by muse, varscan2
- DNAH5 | c.8214C>A p.D2738E | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54202113; called by muse, mutect2, varscan2
- DNAJC13 | c.337-1G>C p.X113_splice | Splice Site (SNP) | VAF 15/68 reads (22%) | catalogued as COSV53445113; called by muse, mutect2, varscan2
- DOT1L | c.2462G>C p.G821A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as COSV67107750; called by muse, mutect2, varscan2
- DPYSL5 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as rs1305646191, COSV56508613; called by muse, mutect2, varscan2
- DRD3 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV55678357; called by muse, mutect2, varscan2
- DSEL | c.532G>T p.V178F | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59489129; called by muse, varscan2
- DSEL | c.531G>C p.E177D | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV59489137; called by muse, mutect2, varscan2
- EFCAB12 | c.860G>C p.R287T | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV100394813, COSV58174694; called by muse, mutect2, varscan2
- EIF2B5 | c.1693G>A p.V565I (on ENST00000647909; = p.V557I on NM_003907.3) | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV56603550; called by muse, mutect2
- ENAM | c.948T>G p.I316M | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV68535154; called by muse, mutect2, varscan2
- EPRS1 | c.3571G>C p.D1191H | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV65096990; called by muse, mutect2, varscan2
- FANCC | c.1550A>T p.E517V | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.328); catalogued as COSV56656451; called by muse, mutect2, varscan2
- FAR1 | c.374T>C p.V125A | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV61383923; called by muse, mutect2, varscan2
- FBN2 | c.695T>A p.I232N | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV52490607; called by muse, mutect2, varscan2
- FGD6 | c.3544A>T p.I1182L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as COSV59690026, COSV59693474; called by muse, mutect2, varscan2
- FKBP8 | c.722C>T p.A241V (on ENST00000222308 / NM_001308373.2; = p.A242V on NM_012181.5) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as COSV55890999; called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.26); catalogued as COSV52545747; called by muse, mutect2, varscan2
- FRK | c.277A>G p.S93G | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1299828815, COSV74176942; called by muse, mutect2, varscan2
- FRMPD2 | c.2531G>C p.R844T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.647); catalogued as COSV59714797; called by muse, mutect2, varscan2
- GBF1 | c.3814G>C p.E1272Q (on ENST00000369983 / NM_001377137.1; = p.E1271Q on NM_004193.3) | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV64142515; called by muse, mutect2, varscan2
- GDI1 | c.215G>A p.W72* | Nonsense Mutation (SNP) | VAF 100/113 reads (88%) | catalogued as COSV63895180; called by muse, mutect2, varscan2
- GFRA2 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1267008846; called by muse, varscan2
- GPN1 | c.85G>T p.G29* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV53112382; called by mutect2, varscan2
- GRIA4 | c.384C>G p.S128R | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.44); PolyPhen benign (0.043); catalogued as COSV56880162, COSV56905602; called by muse, mutect2, varscan2
- GRIA4 | c.1495G>T p.A499S | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV56880172; called by muse, mutect2, varscan2
- GUCY1A2 | c.1660G>C p.D554H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56476620; called by muse, mutect2
- GUCY1A2 | c.429del p.N144Tfs*21 | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | catalogued as COSV56477971; called by mutect2, pindel, varscan2
- HCN1 | c.2228C>A p.P743Q | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV57491706, COSV57502530; called by mutect2, varscan2
- HCN1 | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 59/96 reads (61%) | catalogued as COSV100301761, COSV57491725, COSV57514836; called by muse, mutect2, varscan2
- HECW2 | c.2876G>T p.R959M | Missense Mutation (SNP) | VAF 53/58 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV53648011; called by muse, mutect2, varscan2
- HHIPL2 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV58563041; called by muse, mutect2, varscan2
- HOXB7 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs748728131, COSV53309817, COSV99494095; called by muse, mutect2, varscan2
- HSPA4 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as rs1428009361, COSV59181546; called by muse, mutect2, varscan2
- HTRA4 | c.497A>G p.N166S | Missense Mutation (SNP) | VAF 67/96 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV56758196; called by muse, mutect2, varscan2
- HYDIN | c.9222C>G p.N3074K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99993543; called by muse, mutect2, varscan2
- IL6ST | c.1602A>T p.E534D | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV61139572; called by muse, mutect2, varscan2
- INHA | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 57/64 reads (89%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as COSV54712264; called by muse, mutect2, varscan2
- KCNH3 | c.2200G>C p.D734H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV57789250; called by muse, mutect2
- KCNH8 | c.2376G>T p.K792N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV60455802; called by muse, mutect2, varscan2
- KCNJ10 | c.167G>A p.W56* | Nonsense Mutation (SNP) | VAF 29/155 reads (19%) | catalogued as COSV63632757; called by muse, mutect2, varscan2
- KDR | c.2372G>C p.R791P | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55757419, COSV55763403; called by muse, mutect2, varscan2
- KIT | c.528A>T p.K176N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV55387292; called by muse, mutect2, varscan2
- KL | c.2803T>A p.F935I | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as COSV66307718; called by muse, mutect2, varscan2
- KLHL7 | c.1296C>G p.I432M (on ENST00000339077 / NM_001031710.3; = p.I384M on NM_018846.5) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV59159540; called by muse, mutect2, varscan2
- KMT2C | c.6244A>G p.I2082V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765573319, COSV51277655; called by muse, mutect2, varscan2
- KRT74 | c.1268G>C p.R423P | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV59770408; called by muse, mutect2, varscan2
- KRT74 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as COSV59770414; called by muse, mutect2, varscan2
- KRT77 | c.718G>T p.V240F | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV59238267; called by muse, mutect2
- KRT84 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.881); catalogued as COSV57770490; called by muse, mutect2, varscan2
- KRTAP13-1 | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as rs1187659142, COSV62662628; called by muse, mutect2, varscan2
- LIG4 | c.2501A>T p.E834V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as COSV63596299; called by muse, mutect2, varscan2
- LMO7 | c.1974G>T p.E658D (on ENST00000357063; = p.E388D on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV58529477; called by muse, mutect2, varscan2
- LRG1 | c.748A>T p.R250W | Missense Mutation (SNP) | VAF 102/165 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV56702221; called by muse, mutect2, varscan2
- LRRK2 | c.3342A>T p.L1114F | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as CS053469, COSV54142394; called by muse, mutect2, varscan2
- LRRTM4 | c.373C>G p.H125D | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.186); catalogued as COSV69138846, COSV69140513; called by muse, mutect2, varscan2
- LY6G5C | c.677A>T p.*226Lext*52 (on ENST00000375863; = p.*151Lext*52 on NM_025262.3) | Nonstop Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as COSV65497539; called by mutect2, varscan2
- MADCAM1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.46); PolyPhen benign (0.023); catalogued as COSV53127062; called by muse, mutect2, varscan2
- MAGEB6 | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs781316600, COSV66871772; called by muse, mutect2, varscan2
- MAPRE1 | c.197A>C p.K66T | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV65032438; called by muse, mutect2, varscan2
- MASP1 | c.401A>T p.H134L | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV51457135; called by muse, mutect2, varscan2
- MCM2 | c.2057A>T p.H686L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.329); catalogued as rs1443012813, COSV54031860; called by muse, mutect2, varscan2
- MKI67 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.26); catalogued as COSV64072383; called by muse, mutect2, varscan2
- MLYCD | c.642G>T p.E214D | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as COSV52304001, COSV52304458; called by muse, mutect2, varscan2
- MON2 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54802558; called by muse, mutect2
- MROH2B | c.4669C>A p.Q1557K | Missense Mutation (SNP) | VAF 141/273 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as COSV68180753; called by muse, mutect2, varscan2
- MSH6 | c.2065T>G p.F689V | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1558664138, COSV52273740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTCL1 | c.1825G>T p.E609* (on ENST00000306329 / NM_001378206.1; = p.E249* on NM_015210.4) | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV60402728; called by mutect2, varscan2
- MTHFR | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT deleterious (0.05); PolyPhen benign (0.155); catalogued as rs45550133, CM082956; called by muse, mutect2, varscan2
- MUC6 | c.3683C>A p.T1228N | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV70132427; called by muse, mutect2, varscan2
- MYH1 | c.1533G>T p.W511C | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56843217; called by muse, mutect2, varscan2
- MYH1 | c.1532G>T p.W511L | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56843225; called by muse, mutect2, varscan2
- MYH15 | c.2152C>A p.R718S | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as COSV56303902; called by muse, mutect2, varscan2
- NRXN3 | c.596C>A p.P199H (on ENST00000557594 / NM_001272020.2; = p.P831H on NM_004796.6) | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55312518, COSV55355362; called by muse, mutect2, varscan2
- NUP37 | c.430A>T p.S144C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51836961; called by muse, mutect2, varscan2
- OR10J1 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as COSV71128104; called by muse, mutect2, varscan2
- OR14C36 | c.658T>A p.F220I | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV58600411; called by muse, mutect2, varscan2
- OR14K1 | c.106del p.A36Lfs*3 | Frame Shift Del (DEL) | VAF 23/116 reads (20%) | catalogued as rs768945073; called by mutect2, pindel, varscan2
- OR1E2 | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs966611996, COSV50265321; called by muse, mutect2, varscan2
- OR2B2 | c.326C>A p.S109Y | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV57579020; called by muse, mutect2, varscan2
- OR2T33 | c.433T>C p.S145P | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as COSV58813694; called by muse, varscan2
- OR4C6 | c.383T>A p.L128Q | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58602319, COSV58604055; called by muse, mutect2, varscan2
- OR4Q3 | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.088); catalogued as COSV59177186; called by muse, mutect2, varscan2
- OR6C75 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58551112; called by muse, mutect2, varscan2
- OVGP1 | c.812A>T p.K271I | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV63857358; called by muse, mutect2, varscan2
- PAN3 | c.926C>A p.S309* | Nonsense Mutation (SNP) | VAF 38/261 reads (15%) | catalogued as COSV66706996, COSV66708727; called by muse, mutect2, varscan2
- PAPPA2 | c.1645C>A p.L549M | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV62772312; called by muse, mutect2, varscan2
- PATE1 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1555084326, COSV59824074; called by muse, mutect2, varscan2
- PDZD2 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV56849244, COSV99223575; called by muse, mutect2
- PHC2 | c.2467G>C p.G823R (on ENST00000257118 / NM_198040.2; = p.G288R on NM_004427.4) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57101534; called by muse, mutect2, varscan2
- PHC3 | c.1688C>G p.P563R (on ENST00000494943 / NM_001308116.2; = p.P575R on NM_024947.4) | Missense Mutation (SNP) | VAF 360/432 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71948204; called by muse, mutect2, varscan2
- PLCB1 | c.3251A>T p.K1084I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV62036610; called by muse, mutect2, varscan2
- PLEKHH2 | c.1541A>G p.Y514C | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs144437669; called by muse, mutect2, varscan2
- PMFBP1 | c.2665G>C p.D889H (on ENST00000537465; = p.D884H on NM_031293.3) | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52820219; called by muse, mutect2, varscan2
- PPP1R17 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV59610504; called by muse, mutect2, varscan2
- PPP1R3A | c.1574G>A p.G525D | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV52875434; called by muse, mutect2, varscan2
- PRDM13 | c.1748C>A p.S583* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV65028799; called by muse, mutect2, varscan2
- PRR11 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV51874306, COSV99231902; called by muse, mutect2, varscan2
- PRRC2C | c.3742A>T p.S1248C (on ENST00000367742; = p.S1246C on NM_015172.4) | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58900478; called by muse, mutect2, varscan2
- PRRC2C | c.4701G>T p.R1567S (on ENST00000367742; = p.R1565S on NM_015172.4) | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.761); catalogued as COSV58900490; called by muse, mutect2, varscan2
- PSG11 | c.134T>A p.V45E | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60453445; called by muse, mutect2, varscan2
- PTPN1 | c.94T>G p.C32G | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.612); catalogued as COSV63298625; called by muse, mutect2
- PTPRF | c.3431G>T p.G1144V | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.299); catalogued as COSV63442331; called by muse, mutect2, varscan2
- PTPRH | c.1368G>T p.W456C | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.227); catalogued as COSV54742314; called by muse, mutect2, varscan2
- PXDC1 | c.439A>T p.S147C | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV66661204; called by muse, mutect2, varscan2
- RANBP2 | c.2717A>G p.N906S | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs768789460, COSV51695804; called by muse, mutect2, varscan2
- RBL2 | c.1836T>G p.N612K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.395); catalogued as COSV50872773; called by muse, mutect2, varscan2
- RBL2 | c.1837G>T p.E613* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV50872782; called by muse, mutect2, varscan2
- REST | c.1496T>A p.V499E | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1323370113, COSV58359193; called by muse, mutect2
- RNF213 | c.11748C>G p.V3916= | Splice Region (SNP) | VAF 4/15 reads (27%) | catalogued as COSV60389365; called by muse, mutect2, varscan2
- RP1 | c.760G>T p.G254* | Nonsense Mutation (SNP) | VAF 42/55 reads (76%) | catalogued as COSV55109499, COSV55116849; called by muse, mutect2, varscan2
- RPRD1A | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as COSV59821016; called by muse, mutect2, varscan2
- SACS | c.11905C>T p.L3969F | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs780296313, COSV66533461; called by mutect2, varscan2
- SAP130 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 55/64 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as rs1029422515, COSV52093924; called by muse, mutect2, varscan2
- SCYL3 | c.1937C>G p.P646R (on ENST00000367770; = p.P592R on NM_020423.7) | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV53676428; called by muse, mutect2, varscan2
- SDS | c.30G>T p.K10N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV57452512; called by mutect2, varscan2
- SEMA6D | c.822G>C p.W274C | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60372167, COSV60372503; called by muse, mutect2, varscan2
- SI | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 120/135 reads (89%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as COSV52264888; called by muse, mutect2, varscan2
- SIM1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53488667; called by muse, mutect2, varscan2
- SLC26A4 | c.921G>C p.T307= | Splice Region (SNP) | VAF 21/57 reads (37%) | catalogued as COSV55914256; called by muse, mutect2, varscan2
- SLC30A4 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.921); catalogued as COSV56005003; called by muse, mutect2, varscan2
- SLC5A11 | c.1966C>A p.L656M | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.323); catalogued as rs867705072, COSV61739793; called by muse, mutect2, varscan2
- SLC6A5 | c.2017C>G p.P673A | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV54223207; called by muse, mutect2, varscan2
- SLC6A5 | c.2018C>G p.P673R | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as COSV54223216, COSV54227402; called by muse, mutect2, varscan2
- SLMAP | c.2123A>G p.N708S (on ENST00000428312 / NM_001377924.1; = p.N770S on NM_007159.5) | Missense Mutation (SNP) | VAF 52/66 reads (79%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.037); catalogued as COSV55844109; called by muse, mutect2, varscan2
- SMC6 | c.694A>G p.R232G | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.159); catalogued as COSV61171187; called by muse, mutect2, varscan2
- SMG6 | c.3341A>T p.E1114V | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV53962597; called by mutect2, varscan2
- SP4 | c.1957G>A p.G653R | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV56020435; called by muse, mutect2
- SPATA6L | c.1085A>G p.N362S (on ENST00000461761 / NM_001353484.2; = p.N304S on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1033569618, COSV67889412; called by muse, mutect2, varscan2
- SPON1 | c.1551C>A p.C517* | Nonsense Mutation (SNP) | VAF 9/13 reads (69%) | catalogued as COSV59957231; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1940A>G p.D647G | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373393584; called by muse, mutect2, varscan2
- SYCP1 | c.2487T>A p.H829Q | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV65694242; called by muse, mutect2, varscan2
- TADA1 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs367923603; called by muse, mutect2, varscan2
- TAF1C | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV58984396, COSV58984655; called by muse, mutect2, varscan2
- TAF2 | c.3043G>C p.A1015P | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV65416325; called by muse, mutect2, varscan2
- TAL1 | c.582C>A p.S194R | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53745023, COSV53746341; called by muse, mutect2, varscan2
- TAS2R38 | c.322T>A p.W108R | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71884925; called by muse, mutect2, varscan2
- TES | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 34/71 reads (48%) | catalogued as COSV64041701; called by muse, mutect2, varscan2
- TEX15 | c.3011T>A p.L1004* (on ENST00000256246; = p.L1387* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 55/75 reads (73%) | catalogued as COSV56341050; called by muse, mutect2, varscan2
- THEMIS | c.14T>C p.L5P | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64069010; called by muse, mutect2, varscan2
- TMEM132A | c.2728G>C p.D910H (on ENST00000453848 / NM_178031.3; = p.D911H on NM_017870.4) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV50000060; called by muse, mutect2, varscan2
- TRIO | c.8684A>T p.H2895L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV59988436; called by muse, mutect2, varscan2
- TRPC7 | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 56/68 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61452222; called by muse, mutect2, varscan2
- TRPM3 | c.1859G>T p.R620L (on ENST00000357533 / NM_001366142.2; = p.R463L on NM_020952.6) | Missense Mutation (SNP) | VAF 143/173 reads (83%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as COSV62579196; called by muse, mutect2, varscan2
- TULP4 | c.2882A>G p.Y961C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1156485635, COSV65571679; called by muse, mutect2, varscan2
- UBA1 | c.2413G>C p.V805L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV60110843, COSV60111082; called by muse, mutect2
- UNC13C | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV52840856; called by muse, mutect2, varscan2
- UNC13C | c.832T>A p.S278T | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1219059524, COSV52840878; called by muse, mutect2, varscan2
- WASHC4 | c.2903A>G p.K968R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV59888265; called by muse, mutect2, varscan2
- ZEB1 | c.2149C>A p.Q717K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV58035851; called by muse, mutect2, varscan2
- ZFHX4 | c.9511C>A p.P3171T | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV50480098; called by muse, mutect2, varscan2
- ZFPM2 | c.2740A>G p.I914V | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs1228516735, COSV65872415; called by muse, mutect2, varscan2
- ZNF207 | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV58298725; called by muse, mutect2, varscan2
- ZNF33A | c.2293G>C p.V765L (on ENST00000458705 / NM_006974.3; = p.V766L on NM_006954.2) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.159); catalogued as COSV56722747; called by muse, mutect2, varscan2
- ZNF34 | c.1303G>T p.V435L | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as COSV58638123; called by muse, mutect2, varscan2
- ZNF446 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59990824; called by muse, mutect2, varscan2
- ZNF483 | c.586A>C p.K196Q | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV58514414; called by muse, mutect2
- ZNF518B | c.2688A>T p.L896F | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV58721135; called by muse, mutect2, varscan2
- ZNF556 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs374705626, COSV56910734, COSV56913508; called by muse, varscan2
- ZNF646 | c.2248G>A p.G750S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs745307658, COSV54922483; called by muse, varscan2
- ZNF701 | c.667G>A p.E223K (on ENST00000301093; = p.E157K on NM_018260.3) | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.08); catalogued as rs755339209, COSV56522851; called by muse, mutect2, varscan2
- ZNF714 | c.719A>G p.H240R | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs990040786, COSV52509550; called by muse, mutect2, varscan2
- ZNHIT1 | c.302A>G p.Y101C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV59312415; called by muse, mutect2, varscan2
- BSN | c.8182G>A p.G2728S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by mutect2, varscan2
- CD163L1 | c.425dup p.D142Efs*9 | Frame Shift Ins (INS) | VAF 4/45 reads (9%) | called by mutect2, varscan2
- CD163L1 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CWC27 | c.552del p.E185Rfs*7 | Frame Shift Del (DEL) | VAF 23/39 reads (59%) | called by mutect2, pindel, varscan2
- CYBB | c.992del p.K331Rfs*12 | Frame Shift Del (DEL) | VAF 25/45 reads (56%) | called by mutect2, pindel, varscan2
- CYP1A1 | c.910_929del p.D304Rfs*10 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- H3-5 | c.85del p.S29Afs*8 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- IRGQ | c.1224_1226del p.E409del | In Frame Del (DEL) | VAF 31/88 reads (35%) | called by mutect2, pindel, varscan2
- KLHL32 | c.893dup p.R299Afs*16 | Frame Shift Ins (INS) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- MUC13 | c.696_697del p.K233Tfs*10 | Frame Shift Del (DEL) | VAF 44/90 reads (49%) | called by pindel, varscan2
- NXF3 | c.1073_1074del p.S358Wfs*8 | Frame Shift Del (DEL) | VAF 36/72 reads (50%) | called by pindel, varscan2
- OR2G2 | c.265dup p.W89Lfs*26 | Frame Shift Ins (INS) | VAF 48/108 reads (44%) | called by mutect2, pindel, varscan2
- PCDH17 | c.2270del p.G757Afs*24 | Frame Shift Del (DEL) | VAF 18/41 reads (44%) | called by mutect2, pindel*, varscan2
- SPANXB1 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TAOK1 | c.2783_2785delinsTT p.G928Vfs*42 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by pindel, varscan2*
- UBE2NL | c.349A>C p.N117H | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- VN1R5 | c.753T>A p.S251R | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ABLIM1 | c.1251A>G p.K417= | Silent (SNP) | VAF 49/65 reads (75%) | catalogued as COSV53299029; called by muse, mutect2, varscan2
- ADCK1 | c.510G>C p.G170= | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as COSV53078096; called by muse, mutect2, varscan2
- ANO3 | c.1536A>T p.T512= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV56778832; called by muse, mutect2, varscan2
- ATP13A3 | c.2457G>A p.E819= | Silent (SNP) | VAF 18/164 reads (11%) | catalogued as COSV55461229, COSV99756977; called by muse, mutect2, varscan2
- BOC | c.1509G>C p.A503= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV56346767; called by muse, mutect2
- CD300C | c.456C>A p.P152= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs1161108914, COSV58169483; called by muse, mutect2, varscan2
- CILP | c.217C>A p.R73= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV56021683; called by muse, mutect2, varscan2
- CINP | c.381T>C p.Y127= | Silent (SNP) | VAF 24/39 reads (62%) | catalogued as COSV53735853; called by muse, mutect2, varscan2
- CSF2RB | c.2136C>A p.V712= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV53255268; called by muse, mutect2, varscan2
- DCAF8 | c.651G>A p.V217= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100470748; called by muse, varscan2
- EPG5 | c.6480G>T p.S2160= | Silent (SNP) | VAF 37/57 reads (65%) | catalogued as COSV56344288; called by muse, mutect2, varscan2
- FANCL | c.621C>A p.I207= | Silent (SNP) | VAF 58/86 reads (67%) | catalogued as COSV52072490; called by muse, mutect2, varscan2
- FCRL4 | c.1383G>A p.L461= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs1378346049, COSV54859398; called by muse, mutect2
- FKBP6 | c.969A>T p.T323= | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as COSV52718640; called by muse, mutect2, varscan2
- FLT4 | c.1737A>G p.Q579= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV56097548; called by muse, mutect2, varscan2
- FOSB | c.597G>T p.S199= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV62278358; called by muse, mutect2, varscan2
- FOXP2 | c.702C>T p.L234= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs773700780, COSV63481877; called by muse, mutect2, varscan2
- HCN1 | c.1974C>G p.S658= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV57491719; called by muse, mutect2, varscan2
- HOXA2 | c.444T>A p.T148= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV56065031; called by muse, mutect2, varscan2
- JOSD1 | c.405C>G p.L135= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV53265192; called by muse, mutect2, varscan2
- LAMA2 | c.5127C>T p.A1709= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as COSV70337371; called by muse, mutect2, varscan2
- LRRTM4 | c.945C>T p.C315= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV69138839; called by mutect2, varscan2
- MAP3K4 | c.711A>T p.S237= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV62329927; called by muse, mutect2, varscan2
- MBOAT7 | c.426G>A p.L142= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV55473895; called by muse, mutect2, varscan2
- MC5R | c.291C>T p.Y97= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV61253814; called by muse, mutect2
- MGAM | c.5241G>A p.G1747= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV72073518; called by muse, mutect2
- MGAT4C | c.1014T>A p.P338= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV59829466, COSV59835291; called by muse, mutect2, varscan2
- MON2 | c.648A>T p.A216= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV54802569; called by muse, mutect2
- MSLNL | c.991C>T p.L331= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV53498943; called by muse, varscan2
- MUC16 | c.1578G>A p.Q526= | Silent (SNP) | VAF 43/89 reads (48%) | catalogued as COSV67442338; called by muse, mutect2, varscan2
- MUC3A | c.8316T>C p.T2772= | Silent (SNP) | VAF 85/409 reads (21%) | catalogued as rs1169180772, COSV60209781; called by muse, mutect2, varscan2
- NBEA | c.201C>T p.I67= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs762992089, COSV59757784; called by muse, mutect2, varscan2
- NKRF | c.1191T>C p.S397= | Silent (SNP) | VAF 77/87 reads (89%) | catalogued as COSV58660540; called by muse, mutect2, varscan2
- NLRC3 | c.397C>A p.R133= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV57086667; called by mutect2, varscan2
- OR14I1 | c.228G>T p.V76= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100700523, COSV61198861; called by muse, mutect2, varscan2
- OR1A2 | c.651T>C p.Y217= | Silent (SNP) | VAF 117/152 reads (77%) | catalogued as rs754901352, COSV67936055; called by muse, mutect2, varscan2
- OR2T34 | c.90C>G p.A30= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV100170510; called by muse, mutect2, varscan2
- OR4Q3 | c.141C>A p.V47= | Silent (SNP) | VAF 47/92 reads (51%) | catalogued as COSV59177176; called by muse, mutect2, varscan2
- OR51M1 | c.408G>T p.V136= | Silent (SNP) | VAF 88/129 reads (68%) | catalogued as COSV60783698; called by muse, mutect2, varscan2
- OR8A1 | c.864C>A p.I288= | Silent (SNP) | VAF 23/31 reads (74%) | catalogued as COSV52507856; called by muse, mutect2, varscan2
- OR9A2 | c.534G>C p.G178= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV63306266; called by muse, mutect2, varscan2
- OSBPL1A | c.2043G>A p.G681= (on ENST00000319481 / NM_080597.4; = p.G168= on NM_018030.4) | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100111072, COSV60194865; called by muse, mutect2, varscan2
- PAPPA2 | c.5151G>A p.R1717= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as rs1557879580, COSV62790071, COSV62800467; called by muse, mutect2, varscan2
- PARP4 | c.2871C>G p.L957= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as rs1203169824, COSV67960199; called by muse, mutect2, varscan2
- PARVB | c.648G>T p.L216= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV58683566; called by muse, mutect2, varscan2
- PAX1 | c.684G>T p.L228= | Silent (SNP) | VAF 30/45 reads (67%) | catalogued as COSV68270996; called by muse, mutect2, varscan2
- PHTF2 | c.681A>G p.T227= (on ENST00000248550 / NM_001366089.1; = p.T189= on NM_020432.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as COSV50323526; called by muse, mutect2, varscan2
- PKD1L1 | c.204T>C p.C68= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV56957431; called by muse, mutect2, varscan2
- PLCL1 | c.774T>C p.I258= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as rs1278155668, COSV70820645; called by muse, mutect2, varscan2
- POLR1A | c.2041C>T p.L681= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as COSV55688813; called by muse, mutect2, varscan2
- PRG4 | c.2637G>A p.E879= | Silent (SNP) | VAF 186/308 reads (60%) | catalogued as COSV63354821; called by muse, mutect2, varscan2
- RBBP6 | c.5094C>G p.V1698= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV60502898; called by muse, mutect2, varscan2
- RIOX2 | c.1365C>A p.S455= (on ENST00000333396 / NM_001042533.2; = p.S454= on NM_032778.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/222 reads (8%) | catalogued as COSV51709231; called by muse, mutect2
- SAMD8 | c.63G>A p.L21= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV65508983; called by muse, mutect2, varscan2
- SENP2 | c.204C>T p.S68= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as COSV56192314; called by muse, mutect2
- SLC12A5 | c.198G>A p.K66= (on ENST00000454036 / NM_001134771.2; = p.K43= on NM_020708.5) | Silent (SNP) | VAF 47/129 reads (36%) | catalogued as COSV54787628, COSV54790950, COSV54791235; called by muse, mutect2, varscan2
- SLTM | c.144C>G p.L48= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV51053132, COSV99989355; called by muse, mutect2
- SORCS3 | c.1317C>T p.I439= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs1374441383, COSV63801918; called by muse, mutect2, varscan2
- SPATA31E1 | c.1266C>A p.V422= | Silent (SNP) | VAF 87/109 reads (80%) | catalogued as COSV57789358; called by muse, mutect2, varscan2
- SYNE1 | c.6147T>C p.D2049= (on ENST00000367255 / NM_182961.4; = p.D2056= on NM_033071.3) | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV54898547; called by muse, mutect2, varscan2
- TASOR2 | c.6810T>C p.D2270= | Silent (SNP) | VAF 45/216 reads (21%) | catalogued as COSV60165227; called by muse, mutect2, varscan2
- TCERG1L | c.597T>G p.A199= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as COSV64046041; called by muse, mutect2, varscan2
- TCHHL1 | c.1011A>G p.G337= | Silent (SNP) | VAF 52/233 reads (22%) | catalogued as COSV64284752; called by muse, mutect2, varscan2
- UBAP1 | c.624G>C p.V208= | Silent (SNP) | VAF 12/192 reads (6%) | catalogued as COSV52657079; called by muse, mutect2
- UBXN6 | c.588G>A p.K196= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV100011217, COSV56670022; called by muse, mutect2, varscan2
- UNC13C | c.4170G>C p.G1390= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs772637365, COSV52840893, COSV99524259; called by muse, mutect2, varscan2
- ZNF213 | c.363G>A p.E121= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs760414212, COSV67727429; called by muse, mutect2, varscan2
- ZNF556 | c.483C>G p.S161= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV56910722; called by muse, varscan2
- ZNF586 | c.318C>T p.P106= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV66972101; called by muse, mutect2, varscan2
- AL590867.2 | n.244G>T | RNA (SNP) | VAF 47/149 reads (32%) | called by muse, mutect2, varscan2
- AL590867.2 | n.243G>T | RNA (SNP) | VAF 46/146 reads (32%) | called by muse, mutect2, varscan2
- HLA-DRB9 | n.86G>C | RNA (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2
- MTRNR2L6 | chr7:142671173 G>A | 3'Flank (SNP) | VAF 12/106 reads (11%) | called by muse, varscan2
- PRR12 | c.51+580G>T | Intron (SNP) | VAF 13/27 reads (48%) | catalogued as COSV101330839, COSV69816564; called by muse, mutect2, varscan2
- SNORD115-18 | n.3G>A | RNA (SNP) | VAF 55/246 reads (22%) | catalogued as rs1269984314; called by muse, mutect2, varscan2
- VNN3 | c.*602C>T | 3'UTR (SNP) | VAF 58/120 reads (48%) | catalogued as COSV99258121, COSV99258503; called by muse, mutect2, varscan2
